Gene-level copy-number profile of tumor specimen TCGA-2H-A9GL-01A from TCGA case TCGA-2H-A9GL, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 74.2 years (27,115 days).
Specimen TCGA-2H-A9GL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.6afee560-78e6-4b90-b267-57b5e58395a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GL-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0340487b-1a33-4514-af42-d4d247627c5a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,270; copy number 2: 21,127; copy number 3: 29,946; copy number 4: 3,881; copy number 5: 268; copy number 6: 204; copy number 7: 352; copy number 8: 620; copy number 9: 120; copy number 28: 15; copy number 32: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GL-01A-12D-A37B-01): tumor purity 0.75, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr16:78,872,739–79,017,429, 6 genes: AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,115 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:52,297,995–52,572,522, 5 genes, copy number 8: Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1.
- chr5:10,057,502–55,110,252, 582 genes, copy number 7–9 (broad region; genes not listed).
- chr8:127,663,280–129,683,770, 23 genes, copy number 28–32: AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr20:87,250–16,053,197, 291 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:15,021,553–25,245,229, 214 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 874. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
